CCDI case PBBYZB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4e457d8f-fbbe-4b58-952c-56b2365bd5fb

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.1 years (2,214 days).

Biospecimens (3 samples)
- Sample 0DL0IY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL0J7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL0JE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
